Gene-level copy-number profile of tumor specimen ALCH-B4XG-TTP1-A from ALCHEMIST case ALCH-B4XG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.0 years (22,641 days).
Specimen ALCH-B4XG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4db013e1-cb87-4048-8829-ddea4cd62356.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4XG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,776 have no estimate.
https://portal.gdc.cancer.gov/files/51106095-679e-4cd5-bbd1-ed8354bd4362

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 172; copy number 1: 22,762; copy number 2: 34,543; copy number 3: 961; copy number 4: 371; copy number 5: 22; copy number 6: 12; copy number 7: 1; copy number 10: 1; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 172 genes in 59 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:26,149,204–26,162,554, 3 genes: SMARCE1P6, AC011742.1, PPIL1P1.
- chr3:47,413,681–47,477,126, 2 genes: SCAP, AC099778.2.
- chr3:47,802,909–47,850,195, 3 genes: DHX30, AC026318.1, MIR1226.
- chr3:49,029,707–49,094,363, 2 genes: QRICH1, RN7SL182P.
- chr3:75,415,070–75,435,110, 2 genes: ALG1L6P, FAM86DP.
- chr3:129,998,531–130,013,541, 2 genes: AC083906.1, AC083906.2.
- chr8:38,105,493–38,144,076, 3 genes (within-gene range 0–1): ASH2L, RNU6-988P, AC084024.1.
- chr8:54,130,582–54,152,882, 3 genes: Metazoa_SRP, MRPL15, RNU6ATAC32P.
- chr9:61,190,003–61,627,683, 9 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr12:31,791,185–31,959,316, 7 genes (within-gene range 0–1): H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1.
- chr12:109,783,087–109,833,436, 2 genes: TRPV4, MIR4497.
- chr13:18,467,172–19,227,432, 36 genes: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1.
- chr17:1,420,689–1,463,162, 2 genes: CRK, AC032044.1.
- chr17:1,516,931–1,518,096, 1 gene (within-gene range 0–1): PITPNA-AS1.
- chr17:1,604,374–1,604,672, 1 gene (within-gene range 0–1): RN7SL105P.
- chr17:1,725,748–1,738,585, 1 gene (within-gene range 0–1): AC130343.1.
- chr17:4,556,927–4,704,337, 9 genes (within-gene range 0–1): GGT6, AC118754.2, TXNP4, SMTNL2, LINC01996, RNU6-955P, ALOX15, PELP1, AC091153.2.
- chr17:16,217,191–16,353,656, 3 genes (within-gene range 0–1): PIGL, MIR1288, CENPV.
- chr17:16,414,524–16,478,678, 8 genes (within-gene range 0–1): AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65.
- chr17:19,496,943–19,497,528, 1 gene (within-gene range 0–1): RPL17P43.
- chr17:19,678,288–19,722,428, 2 genes: SLC47A2, AC005722.3.
- chr17:19,855,747–19,868,689, 2 genes (within-gene range 0–1): AC015726.3, AC015726.2.
- chr17:20,323,001–20,323,337, 2 genes (within-gene range 0–1): RNU6-467P, AC008088.1.
- chr17:20,512,560–20,528,687, 3 genes (within-gene range 0–1): KRT17P6, KRT17P7, AC015818.6.
- chr17:20,543,481–20,550,963, 2 genes: TBC1D3P3, AC015818.8.
- chr17:28,879,335–28,897,733, 2 genes: FLOT2, AC024267.3.
- chr17:29,569,580–29,570,519, 1 gene (within-gene range 0–1): AC104564.3.
- chr17:30,194,319–30,236,002, 2 genes (within-gene range 0–1): SLC6A4, AC104984.1.
- chr17:31,851,871–31,859,291, 1 gene: COPRS.
- chr17:32,280,387–32,280,953, 1 gene (within-gene range 0–1): AC026620.1.
- chr17:37,375,985–37,392,708, 2 genes (within-gene range 0–1): C17orf78, AC243654.3.
- chr17:38,297,023–38,323,217, 1 gene: MRPL45.
- chr18:21,182,503–21,241,371, 2 genes: EXOGP1, AC022809.1.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:13,905,960–13,980,437, 4 genes: SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P.
- chr21:17,431,547–17,707,455, 12 genes: RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2.
- chr21:21,655,038–21,737,319, 2 genes: AF241725.1, LINC00317.
- chr21:31,118,416–31,559,977, 3 genes (within-gene range 0–1): TIAM1, AP000248.1, AP000563.1.
- chr22:29,306,582–29,319,679, 3 genes: GAS2L1, RASL10A, AC002059.1.
- chr22:33,104,330–33,145,861, 2 genes (within-gene range 0–1): LINC01640, Z82198.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:74,505,043–74,507,695, 1 gene, copy number 5: PCGF1.
- chr3:195,514,428–195,543,386, 2 genes, copy number 5: PPP1R2, RNU6ATAC24P.
- chr4:9,210,657–9,231,233, 5 genes, copy number 5: USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P.
- chr6:32,552,713–32,589,848, 2 genes, copy number 6: HLA-DRB6, HLA-DRB1.
- chr8:120,812,219–120,813,359, 1 gene, copy number 5 (within-gene range 3–5): AC104958.2.
- chr8:142,111,414–142,185,527, 2 genes, copy number 5: AC103758.1, MIR4472-1.
- chr8:144,051,266–144,063,965, 2 genes, copy number 6 (within-gene range 2–6): OPLAH, MIR6846.
- chr8:144,409,492–144,416,844, 2 genes, copy number 5: AC233992.3, SLC39A4.
- chr8:144,509,070–144,517,845, 3 genes, copy number 6: MFSD3, RECQL4, AC084125.4.
- chr9:61,865,755–61,866,965, 1 gene, copy number 10: AL391987.4.
- chr16:629,239–636,366, 2 genes, copy number 5 (within-gene range 2–5): WFIKKN1, METTL26.
- chr16:680,224–684,528, 2 genes, copy number 14 (within-gene range 2–14): STUB1, JMJD8.
- chr16:991,151–1,000,926, 1 gene, copy number 5: AC009041.1.
- chr16:1,088,226–1,105,461, 2 genes, copy number 5–7: C1QTNF8, AL031713.1.
- chr17:20,449,395–20,467,539, 1 gene, copy number 6: LGALS9B.
- chr17:67,224,303–67,225,541, 2 genes, copy number 5 (within-gene range 2–5): AC007448.3, RPL36AP48.
- chr17:76,265,348–76,271,298, 1 gene, copy number 5: UBALD2.
- chr17:81,927,829–81,942,412, 3 genes, copy number 6 (within-gene range 1–6): MAFG-DT, PYCR1, AC145207.4.
- chr22:15,572,089–15,573,265, 1 gene, copy number 6: AP000533.1.
- chr22:38,335,762–38,398,929, 2 genes, copy number 5 (within-gene range 2–5): TPTEP2, Z98749.1.

Autosomal genes at a single copy (total copy number 1): 19,906. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
